Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16J-01A (Primary Tumor).

[page 1 of 6]
ICD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

12/4/10

lv

Site Code: Endometrium- C54.1

Surgical Pathology

TISSUE DESCRIPTION:

J1 J2 J3 J4 K1 K2 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10

C1 C2 C3

C4 C5 C6 C7 C8 C9 C10 C11 C12 D1 D2 D3 D4 D5 D6 D7 D8 D9
D10 D11 D12

D13 D14 D15 D16 D17 D18 D19 D20 D21 D22 D23 D24 D25 D26
D27 D28 D29

E1 F1 G1 G2 G3 H1 H2 I1 I2 I3 I4

A. Received fresh labeled "abdominal pannus" is a 3090.0
gram

portion of skin and subcutaneous tissue with umbilicus.

No lesions

identified.

B. Received fresh labeled "uterus, right and left
fallopian tubes
and ovaries" is a 85.0 gram uterus with attached bilateral
tubes and

ovaries and hemorrhagic cervix. The uterine serosa is
smooth.

There is a 3.9 x 2.9 x 1.5 cm mass in the lower uterine
segment to

the endocervical canal of the endometrial cavity with 0.9
cm

myometrial thickness. There are no leiomyomata. There is
a 3.2 x

1.4 x 1.4 cm right ovary with a smooth outer surface and a
7.3 x 0.8

cm right fallopian tube. There is a 2.8 x 1.4 x 1.4 cm
left ovary

with a smooth outer surface and a 6.2 x 0.7 cm left
fallopian tube

with multiple paratubal cysts (ranging in size from 0.2 cm
to 0.4 cm

in greatest dimension). Representative sections
submitted. Grossed

C. Received fresh labeled "right pelvic nodes: external"
is a 7.0

x 6.0 x 3.0 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

[page 2 of 6]
Received fresh labeled "right pelvic nodes: internal" is a
0.7 x 0.7
x 0.4 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

Received fresh labeled "right pelvic nodes: common" is a
4.5 x 4.2 x
1.2 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

Received fresh labeled "right pelvic nodes: obturator" is
a 8.0 x
7.0 x 2.5 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

D. Received fresh labeled "left pelvic nodes: obturator"
is a 9.8 x
6.5 x 2.8 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

Received fresh labeled "left pelvic nodes: external" is a
7.2 x 5.5
x 1.7 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

Received fresh labeled "left pelvic nodes: internal" is a
4.0 x 3.2
x 1.0 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

Received fresh labeled "left pelvic nodes: common" is a
4.2 x 1.8 x
1.2 cm aggregate of adipose and lymphatic tissue. All
lymphatic
tissue submitted.

E. Received fresh labeled "right gonadal vessels" is a
6.0 cm in
length by 0.4 cm in diameter portion of unremarkable blood
vessel.
A representative section is submitted.

[page 3 of 6]
F. Received fresh labeled "left gonadal vessels" is a 5.4 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

G. Received fresh labeled "right para-aortic nodes above the

inferior mesenteric artery" is a 4.0 x 3.0 x 1.5 cm aggregate of

adipose and lymphatic tissue. One lymph node is transected, and

half of the node is in the right above the inferior mesenteric

artery and half is below the inferior mesenteric artery specimen.

All lymphatic tissue submitted.

H. Received fresh labeled "right para-aortic nodes below the

inferior mesenteric artery" is a 3.0 x 2.3 x 1.5 cm aggregate of

adipose and lymphatic tissue. All lymphatic tissue submitted.

Grossed by .

I. Received fresh labeled "left para-aortic nodes above the

inferior mesenteric artery" is a 4.0 x 3.5 x 1.5 cm aggregate of

adipose and lymphatic tissue. All lymphatic tissue submitted.

Grossed by .

J. Received fresh labeled "left para-aortic nodes below the

inferior mesenteric artery" is a 4.5 x 2.8 x 1.5 cm aggregate of

adipose and lymphatic tissue. All lymphatic tissue submitted.

Grossed by .

K. Received fresh labeled "omental bx" is a 19.2 x 7.1 x 0.8 cm

portion of omentum. No masses are identified grossly. Lymph nodes

[page 4 of 6]
are not identified. Representative sections submitted.
Grossed by

DIAGNOSIS:

A. Abdomen, panniculectomy: Skin and subcutaneous tissue (3090.0 grams) with umbilicus identified grossly. Gross examination only.

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (3.9 x 2.9 x 1.5 cm) in the lower uterine segment extending into the endocervical canal and invading through the myometrial wall (0.9 cm thickness), but not through to the uterine serosa. No lymphovascular space invasion is identified. The ectocervical margin is negative for malignancy (by 0.5 cm). The right and left ovaries and tubes are uninvolved. The left fallopian tube has multiple paratubal cysts (ranging in size from 0.2 cm to 0.4 cm in greatest dimension). Multiple (2) regional lymph nodes are negative for malignancy.

C. Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (5 external iliac, 2 internal iliac, 5 common iliac, 10 obturator) are negative for tumor.

D. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (8 external iliac, 4 internal iliac, 1 common iliac, 16 obturator) are negative for tumor.

[page 5 of 6]
E. Gonadal vessels, right, excision: Negative for malignancy.

F. Gonadal vessels, left, excision: Negative for malignancy.

G. Lymph nodes, right para-aortic above the inferior mesenteric artery, lymphadenectomy: Multiple (4) lymph nodes are negative for malignancy.

H. Lymph nodes, right para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple (2) lymph nodes are negative for malignancy.

I. Lymph nodes, left para-aortic above the inferior mesenteric artery, lymphadenectomy: Multiple (4) lymph nodes are negative for malignancy.

J. Lymph nodes, left para-aortic below the inferior mesenteric artery, lymphadenectomy: Multiple (3) lymph nodes are negative for malignancy.

K. Omentum, omentectomy: Negative for malignancy.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

ADDENDUM:

Review of the permanent sections with specific determination of the extent of cervical involvement was requested by The

cervical section reveals tumor infiltration within the stroma

[page 6 of 6]
beneath the cervical transformation zone mucosa.

Source: NCI Genomic Data Commons file 3454b1cf-3424-44a6-b5dc-0bc6a9716f1a (TCGA-D1-A16J.7A1F7567-5D17-4074-B099-1E60C8069FA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).